Somatic mutation profile of tumor specimen TCGA-AX-A062-01A (aliquot TCGA-AX-A062-01A-11W-A027-09) from TCGA case TCGA-AX-A062, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 53.8 years (19,643 days).
Specimen TCGA-AX-A062-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92a65ca5-e5f0-4f21-9822-66ed4e6e9600.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A062-10A (Blood Derived Normal), aliquot TCGA-AX-A062-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c449405-69e3-42c0-83e1-e45e5a70418a

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 3, 5'Flank 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 196/222 reads (88%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 62/123 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 58/139 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP1G2 | c.1552A>G p.M518V | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs769210525, COSV55338600; called by muse, mutect2, varscan2
- ARMC4 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 166/362 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV53465418; called by muse, mutect2, varscan2
- C5 | c.3520T>G p.F1174V | Missense Mutation (SNP) | VAF 77/150 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV56327685; called by muse, mutect2, varscan2
- CCND1 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV57121314; called by muse, varscan2
- CD163L1 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1348308236, COSV58016221, COSV58016973; called by muse, mutect2, varscan2
- CRYBB2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs776010780, COSV101236768, COSV101236770, COSV68005498; called by muse, mutect2, varscan2
- CTDSPL | c.637C>T p.R213W (on ENST00000273179 / NM_001008392.2; = p.R202W on NM_005808.3) | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56202261; called by muse, mutect2, varscan2
- MOG | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 74/150 reads (49%) | catalogued as rs201832372, COSV65305893; called by muse, mutect2, varscan2
- NUP88 | c.2203A>G p.I735V | Missense Mutation (SNP) | VAF 182/412 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV52585147; called by muse, mutect2, varscan2
- OR4C13 | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 376/855 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as COSV73648763; called by muse, mutect2, varscan2
- PDE1C | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 212/489 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs780922214, COSV58514408; called by muse, mutect2, varscan2
- PRX | c.3754G>A p.A1252T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1325660660, COSV52521355; called by muse, mutect2
- RIMBP2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs771972257, COSV55470054; called by muse, mutect2, varscan2
- RPL39 | c.46A>G p.K16E | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV64294170; called by muse, mutect2, varscan2
- SCN11A | c.5071G>A p.A1691T | Missense Mutation (SNP) | VAF 145/307 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs754911340, COSV56570998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG8 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs772422031, COSV56285379; called by muse, mutect2, varscan2
- SPOP | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 211/476 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV100753535, COSV61653007; called by muse, mutect2, varscan2
- STAT5B | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752593400, COSV53182781; called by muse, mutect2, varscan2
- TCN1 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57253332; called by muse, mutect2
- TM4SF19 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs564896096, COSV56556710; called by muse, mutect2, varscan2
- ZBBX | c.2314T>C p.S772P | Missense Mutation (SNP) | VAF 107/242 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV56790221; called by muse, mutect2, varscan2
- CLASRP | c.1860_1863del p.K621Sfs*3 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- AC098582.1 | c.561G>A p.L187= | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as rs1479825118, COSV52020556; called by muse, mutect2, varscan2
- ADAMTS16 | c.3633C>T p.Y1211= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs367839151, COSV56979580; called by muse, mutect2, varscan2
- GLI3 | c.2493C>T p.S831= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV67888926; called by muse, mutect2, varscan2
- MON1B | c.975G>A p.V325= | Silent (SNP) | VAF 54/100 reads (54%) | catalogued as rs761250475, COSV50247312; called by muse, mutect2, varscan2
- OR51D1 | c.774C>A p.L258= | Silent (SNP) | VAF 18/516 reads (3%) | catalogued as COSV62914652, COSV62914667; called by muse, mutect2
- PPEF1 | c.1410A>G p.E470= | Silent (SNP) | VAF 147/315 reads (47%) | catalogued as COSV62995788, COSV62996349; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501614 A>G | 5'Flank (SNP) | VAF 51/115 reads (44%) | called by muse, mutect2, varscan2
- MIR543 | n.57G>A | RNA (SNP) | VAF 22/42 reads (52%) | catalogued as rs766725704; called by muse, mutect2, varscan2
